Somatic mutation profile of tumor specimen TCGA-27-2521-01A (aliquot TCGA-27-2521-01A-01W-0837-08) from TCGA case TCGA-27-2521, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 34.7 years (12,685 days).
Specimen TCGA-27-2521-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f228fe68-6bfd-4b47-861f-cd7f42c2bfb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-2521-10A (Blood Derived Normal), aliquot TCGA-27-2521-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c119d8f6-4bc9-40b5-83c3-6558dc5fe50d

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Nonsense Mutation 4, Frame Shift Ins 4, Frame Shift Del 2, Intron 1, Splice Region 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 61/167 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACADVL | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140629318, CM024582, CM990086, COSV50039777; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- ADAMTS8 | c.1819C>A p.L607I | Missense Mutation (SNP) | VAF 28/884 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs1255445380; called by muse, mutect2
- APOA5 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 106/197 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57065142; called by muse, mutect2, varscan2
- ATP6V1C2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 26/381 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267598832, COSV55365148; called by muse, mutect2
- ATRX | c.5219C>G p.S1740* | Nonsense Mutation (SNP) | VAF 50/51 reads (98%) | catalogued as COSV64871214, COSV64883603; called by muse, mutect2, varscan2
- BRCA2 | c.5897A>G p.H1966R | Missense Mutation (SNP) | VAF 91/207 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs80358823, COSV66462449; ClinVar: uncertain significance / likely benign / conflicting interpretations of pathogenicity / benign; called by muse, mutect2, varscan2
- CLSTN2 | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs200855654, COSV71725274; called by muse, mutect2, varscan2
- CRLF2 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.363); catalogued as rs374874204, COSV67494236; called by muse, mutect2, varscan2
- FAAH | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV54546002; called by muse, mutect2, varscan2
- FBXO22 | c.920A>G p.Q307R | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs370353595, COSV57618982; called by muse, mutect2, varscan2
- GDF6 | c.408C>G p.D136E | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.626); catalogued as COSV54627682; called by muse, mutect2, varscan2
- GNGT2 | c.167A>G p.D56G | Missense Mutation (SNP) | VAF 73/556 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV55930341; called by muse, mutect2, varscan2
- GOLGA3 | c.1562A>T p.D521V | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs937056192, COSV52643920; called by muse, mutect2
- GRIP1 | c.2382G>A p.M794I (on ENST00000359742 / NM_001379345.1; = p.M742I on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/564 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1300773016, COSV54043288; called by muse, mutect2
- HIVEP2 | c.2609A>G p.Q870R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV50064910; called by muse, mutect2, varscan2
- HOOK1 | c.893A>T p.E298V | Missense Mutation (SNP) | VAF 83/214 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64620971; called by muse, mutect2, varscan2
- IFNW1 | c.551G>C p.R184T | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV66522492; called by muse, mutect2, varscan2
- IGHV3-21 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 177/495 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.043); catalogued as rs781842811; called by muse, mutect2, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 30/140 reads (21%) | catalogued as rs780982673; called by mutect2, varscan2
- ITGB8 | c.643A>G p.N215D | Missense Mutation (SNP) | VAF 181/309 reads (59%) | SIFT tolerated (0.62); PolyPhen benign (0.018); catalogued as COSV56006364, COSV56014442; called by muse, mutect2, varscan2
- LAMA2 | c.4381G>T p.G1461* | Nonsense Mutation (SNP) | VAF 48/468 reads (10%) | catalogued as COSV70342112, COSV70355214; called by muse, mutect2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 32/195 reads (16%) | catalogued as rs746133895; called by mutect2, varscan2
- MACF1 | c.1772A>T p.E591V | Missense Mutation (SNP) | VAF 131/820 reads (16%) | catalogued as COSV58402859; called by muse, mutect2, varscan2
- MPP7 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 235/644 reads (36%) | catalogued as rs755262754, COSV61738191; called by muse, mutect2, varscan2
- MYO18A | c.4066G>A p.A1356T | Missense Mutation (SNP) | VAF 255/436 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV62873468; called by muse, mutect2, varscan2
- NPHP4 | c.1448C>G p.P483R | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.299); catalogued as rs759608529, COSV65398095; called by muse, varscan2
- OR2Z1 | c.157T>C p.S53P | Missense Mutation (SNP) | VAF 309/518 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV60693353; called by muse, mutect2, varscan2
- ORC5 | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV52402877; called by muse, mutect2, varscan2
- PCOLCE | c.483dup p.R162Afs*45 | Frame Shift Ins (INS) | VAF 4/18 reads (22%) | catalogued as rs761254301; called by pindel, varscan2
- PDE4B | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58496211; called by muse, mutect2, varscan2
- RIOX2 | c.1316A>G p.K439R (on ENST00000333396 / NM_001042533.2; = p.K438R on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV51716222; called by muse, mutect2, varscan2
- RRAD | c.644T>G p.V215G | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100234040, COSV55337669; called by muse, mutect2, varscan2
- SLC13A2 | c.1550T>C p.V517A | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58998866; called by muse, mutect2
- SLITRK6 | c.362A>C p.H121P | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV68391724; called by muse, mutect2
- STAB1 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs771649805, COSV58742683; called by muse, mutect2, varscan2
- STAR | c.180T>C p.G60= | Splice Region (SNP) | VAF 20/65 reads (31%) | catalogued as COSV52418494; called by muse, mutect2, varscan2
- TP53 | c.789del p.L264Yfs*81 | Frame Shift Del (DEL) | VAF 49/65 reads (75%) | catalogued as COSV52935703, COSV53210322; called by mutect2, pindel, varscan2
- WIPI1 | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 123/285 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs1410429795, COSV50931834; called by muse, mutect2, varscan2
- XDH | c.260C>A p.T87N | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65148420; called by muse, mutect2
- ZNF71 | c.71dup p.P25Tfs*53 | Frame Shift Ins (INS) | VAF 24/53 reads (45%) | catalogued as rs768627914; called by mutect2, pindel, varscan2
- ZNF831 | c.4615G>A p.A1539T | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV64045362; called by muse, mutect2
- CIC | c.2872del p.Q958Sfs*9 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- COQ8A | c.1128G>T p.M376I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- LACRT | c.58+2T>A p.X20_splice | Splice Site (SNP) | VAF 23/460 reads (5%) | called by muse, mutect2
- RLF | c.1650G>T p.W550C | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- SUZ12 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- USP53 | c.1728C>A p.S576R | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- ASTN2 | c.3555C>A p.T1185= (on ENST00000313400 / NM_001365069.1; = p.T1134= on NM_014010.5) | Silent (SNP) | VAF 236/367 reads (64%) | catalogued as COSV56015163; called by muse, mutect2, varscan2
- FTSJ3 | c.2511T>A p.R837= | Silent (SNP) | VAF 42/1595 reads (3%) | catalogued as COSV63789248; called by muse, mutect2
- GRM4 | c.1902C>T p.F634= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV65219834; called by muse, mutect2, varscan2
- IFNW1 | c.462G>C p.L154= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as COSV66521772, COSV66522499; called by muse, mutect2, varscan2
- LRRIQ4 | c.1638A>G p.G546= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV52983060; called by muse, mutect2, varscan2
- MAGEB16 | c.486A>G p.L162= | Silent (SNP) | VAF 168/202 reads (83%) | catalogued as rs1184974019, COSV101303264, COSV67874614; called by muse, mutect2, varscan2
- MAPK8IP1 | c.585A>T p.S195= | Silent (SNP) | VAF 26/272 reads (10%) | catalogued as COSV53799906; called by muse, mutect2, varscan2
- NAP1L3 | c.417C>T p.L139= | Silent (SNP) | VAF 14/78 reads (18%) | called by muse, varscan2
- PRAMEF2 | c.93G>A p.L31= | Silent (SNP) | VAF 33/180 reads (18%) | catalogued as COSV53576865, COSV53579341; called by muse, mutect2, varscan2
- SOX30 | c.1464C>T p.S488= | Silent (SNP) | VAF 67/111 reads (60%) | catalogued as rs753364331, COSV53939690; called by muse, mutect2, varscan2
- SPTLC3 | c.399C>G p.A133= | Silent (SNP) | VAF 156/350 reads (45%) | catalogued as COSV65468804; called by muse, mutect2
- TET3 | c.4482C>T p.P1494= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs764597295, COSV69642000; called by muse, mutect2, varscan2
- WDR13 | c.582C>T p.D194= | Silent (SNP) | VAF 85/95 reads (89%) | catalogued as rs782080281, COSV54331717, COSV54333657; ClinVar: likely benign; called by muse, mutect2, varscan2
- DELEC1 | n.586C>G | RNA (SNP) | VAF 33/446 reads (7%) | catalogued as COSV64986694; called by muse, mutect2
- HNRNPU | c.634+1207G>C | Intron (SNP) | VAF 16/283 reads (6%) | catalogued as COSV51694377; called by muse, mutect2
